Surgical pathology report (de-identified scan), TCGA case TCGA-IB-8126, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-8126-01A (Primary Tumor).

[page 1 of 5]
Chart ID:

MRN:
PHN:
ACB:
DOB/Gender:
Telephone:
Encounter:

Location:
Ordering

Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

/)

Specimen Description

- A. Gallbladder at
- B. Common bile duct lymph node at
- C. Tissue from SMA
- D. Whipple's specimen

TCGA-IB-8126

Clinical Information

Pancreatic cancer.
Infectious patient: No
Immunocompromised: No
History of neoplasm: N/A

Diagnosis

A: Gallbladder:

- Chronic cholecystitis.
- Negative for malignancy or dysplasia.

B: Common Bile Duct Lymph Node:

- One reactive lymph node, negative for malignancy.

C: Tissue from SMA:

- Extensive metastatic adenocarcinoma.

D: Pancreas and Duodenum, Whipple Specimen:

Cc:

Chart Request ID:
Print Date/Time:

Pathology: Provider - Permanent
Page 1 of 5

[page 2 of 5]
Location:

MRN:
PHN:
ACB:

Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

- Pancreatic invasive well-differentiated ductal adenocarcinoma (~ 3.5 cm), involving common bile duct, peripancreatic fat and tissue around superior mesentery vein.
- Multifocal PanIN (1- 3).
- Extensive perineural invasion.
- No lymph-vascular invasion identified.
- Pancreatic distal resection margin involved by carcinoma.
- Resection margin of peripancreatic fat is < 0.1 cm from tumor.
- Posterior (uncinate) margin of pancreas free of tumor: at least 1.2 cm away, and 0.6 cm distant from PanIN.
- Common bile duct resection margin free of tumor: ~ 1.3 cm away.
- Ampulla of Vater and duodenal mucosa not involved by tumor.
- Five of ten (5/10) peripancreatic lymph nodes positive for metastatic carcinoma with extranodal extension.
- AJCC Staging: pT4N1Mx.
- See Synoptic Report.

Reported by:

Electronically signed by:

Verified:

Synoptic Report

D: Pancreas (Exocrine), Macroscopic

SPECIMEN:

Head of pancreas
Duodenum
Stomach
Common bile duct
Gallbladder
Superior mesenteric vein

Cc:

Chart Request ID:

Print Date/Time:

Pathology: Provider - Permanent
Page 2 of 5

[page 3 of 5]
Location:

MRN:
PHN:
ACB:

Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

PROCEDURE:

Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

TUMOR SIZE:

Greatest dimension: 3.5 cm

Additional dimensions: 2.8 x 2.5 cm

D: Pancreas (Exocrine), Microscopic

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G1: Well differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades peripancreatic soft tissues

Tumor invades retroperitoneal soft tissue

Tumor invades mesenteric adipose tissue

MARGINS:

Margin(s) involved by invasive carcinoma

Distal pancreatic margin

Invasive carcinoma involves posterior retroperitoneal surface of pancreas

LYMPH-VASCULAR INVASION:

Not identified

PERINEURAL INVASION:

Present

PRIMARY TUMOR (pT):

pT4: Tumor involves the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

ADDITIONAL PATHOLOGIC FINDINGS:

Pancreatic intraepithelial neoplasia (highest grade: PanIN PanIN 1-3)

CLINICAL HISTORY:

Not specified

Gross Description

Received are specimens A to D. All requisitions and specimen containers are labelled with the patient's name
The cassettes and AP identifiers are labelled with the Surgical Number

Cc:

Chart Request ID:

Print Date/Time:

Pathology: Provider - Permanent
Page 3 of 5

[page 4 of 5]
Location:

MRN:
PHN:
ACB:

Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

A. The specimen consists of an intact cholecystectomy specimen measuring 8.5 x 4.0 x 3.5 cm. The serosal surface appears smooth. The cystic duct is patent. Upon opening, no gallstones are identified. The mucosa appears velvety and unremarkable. The cystic wall measures 0.3 cm in maximum thickness. No evidence of tumor is identified. Representative sections are submitted in one cassette. [REDACTED]

B. The specimen consists of one pre-bisected lymph node measuring 2.2 cm in greatest dimension. Attached to the node is a piece of membranous fibrous tissue. The specimen is serially sectioned longitudinally and submitted in toto in four cassette. [REDACTED]

C. The specimen consists of a small nodule which is submitted in toto for QS. [REDACTED]

The entire remnant of the frozen section block is submitted in CQS1. [REDACTED]

D. The specimen consists of a segment of duodenum and portion of gastric pylorus, measuring 19.0 cm long and 6.0 cm in circumference. Attached to the duodenum is a portion of pancreas measuring 4.0 cm in length and 4.5 cm in width, and 2.5 cm in thickness. A minimal amount of fatty tissue is present. The ampulla region of the duodenal mucosa appears prominent but without ulceration or obvious mass. The peripancreatic tissue appears unremarkable. A portion of distal common bile duct is attached, 2.5 cm in length, and 2.0 cm in greatest diameter. The pancreatic resection margin is inked blue and the posterior margin is inked orange. Serial cross-sections through the pancreas reveal an ill-defined whitish solitary mass measuring 3.5 x 2.8 x 2.5 cm. The pancreatic resection margin seems to be involved.

Representative sections are submitted in cassettes labeled as follows:

- D1 - shave margin of common bile duct.
- D2 and D3 - longitudinal section through common bile duct and adjacent pancreatic tumor.
- D4 - cross-section through tumor and pancreatic duct.
- D5 - cross-section through tumor and pancreatic duct.
- D6 and D7 - longitudinal section through pancreatic duct and ampulla.
- D8 and D9 - pancreatic tumor with overlying duodenum.
- D10 - additional longitudinal section through ampulla.
- D11 and D12 - single cross-section of pancreatic tumor.
- D13 - additional cross-section of pancreatic tumor with surrounding tissue.
- D14 and D15 - tumor with pancreatic resection margin.
- D16 and D17 - pancreas with posterior margin.
- D18 - distal margin of duodenum.
- D19 - perpendicular margin of proximal duodenum and gastric pylorus.
- D20 - two peripancreatic lymph nodes with one bisected.
- D21 and D22 - more putative lymph nodes.

Cc:

Chart Request ID:

Print Date/Time:

Pathology: Provider - Permanent
Page 4 of 5

[page 5 of 5]
Location: _____

MRN:
PHN:
ACB: _____

Surgical Pathology Report

Accession Number: _____

Collected Date: _____

Pathologist: _____

Received Date/Time: _____

D23 - cross-section of SMV and SMA with pancreas.

Frozen Section Diagnosis

C. Tissue from SMA:

- Metastatic adenocarcinoma. (Conf # 17).

Reported by: _____

CC: _____

Chart Request ID: _____

Print Date/Time: _____

Pathology: Provider - Permanent
Page 5 of 5

Source: NCI Genomic Data Commons file 70f57e19-f311-4e79-a74e-6c06a84c2e88 (TCGA-IB-8126.165130CB-6C48-4016-9519-F86C563BBA30.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).